Somatic mutation profile of tumor specimen TCGA-V7-A7HQ-01A (aliquot TCGA-V7-A7HQ-01A-11D-A33E-09) from TCGA case TCGA-V7-A7HQ, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 75.8 years (27,684 days).
Specimen TCGA-V7-A7HQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 66e1c37d-5c56-49dc-8218-0eb0f48d3760.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-V7-A7HQ-10A (Blood Derived Normal), aliquot TCGA-V7-A7HQ-10A-01D-A33H-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bd8cd3dd-5cd7-47b8-bf2e-2f97dd73767d

The open-access MAF lists 22 somatic variants for this specimen: 17 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 12, Silent 5, Nonsense Mutation 3, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- INSL3 | c.304C>T p.R102C | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as rs104894698, CM013758, COSV57953682; ClinVar: pathogenic; called by muse, varscan2
- CLU | c.58G>T p.V20F | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100324325; called by muse, mutect2, varscan2
- EPHB2 | c.1913G>A p.G638D (on ENST00000400191 / NM_001309193.2; = p.G639D on NM_004442.7) | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101007152; called by muse, mutect2
- GJA10 | c.790T>C p.Y264H | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.43); PolyPhen benign (0.332); catalogued as COSV101005369; called by muse, mutect2, varscan2
- IRAG2 | c.3683A>C p.H1228P (on ENST00000636465; = p.H273P on NM_006152.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100611819; called by muse, mutect2, varscan2
- MOV10L1 | c.2857G>T p.A953S | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.114); catalogued as COSV99434059; called by muse, mutect2, varscan2
- MRPS26 | c.268C>G p.L90V | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV99848670; called by muse, mutect2, varscan2
- MUC6 | c.641C>A p.T214N | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV101424638; called by muse, mutect2
- MYOF | c.5866A>T p.K1956* | Nonsense Mutation (SNP) | VAF 29/59 reads (49%) | catalogued as COSV100825814; called by muse, mutect2, varscan2
- PRAMEF12 | c.211A>T p.K71* | Nonsense Mutation (SNP) | VAF 23/53 reads (43%) | catalogued as COSV100743328; called by muse, mutect2, varscan2
- PREX2 | c.3883G>A p.E1295K | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs868582467, COSV55755180; called by muse, mutect2, varscan2
- SEMA4A | c.1742C>G p.P581R | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.334); catalogued as COSV100740624; called by muse, mutect2, varscan2
- SOBP | c.727G>A p.G243R | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100433213; called by muse, mutect2, varscan2
- TMEM184A | c.988G>A p.A330T | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.043); catalogued as rs779647150, COSV99868381; called by muse, mutect2, varscan2
- AFTPH | c.1066del p.E356Kfs*55 | Frame Shift Del (DEL) | VAF 24/60 reads (40%) | called by mutect2, pindel, varscan2
- MAP3K1 | c.1658dup p.Y553* | Nonsense Mutation (INS) | VAF 15/41 reads (37%) | called by mutect2, pindel, varscan2
- MAP3K1 | c.2655dup p.Q886Afs*18 | Frame Shift Ins (INS) | VAF 7/25 reads (28%) | called by mutect2, pindel, varscan2
- DDX56 | c.678T>G p.P226= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as rs767650743, COSV99346121; called by muse, mutect2, varscan2
- DNAJC16 | c.1047C>T p.I349= | Silent (SNP) | VAF 12/25 reads (48%) | catalogued as COSV101012593; called by muse, mutect2, varscan2
- KMT2B | c.528C>T p.T176= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as COSV99386106; called by muse, mutect2, varscan2
- WDR75 | c.1563C>G p.V521= | Silent (SNP) | VAF 16/65 reads (25%) | catalogued as COSV100134261; called by muse, mutect2, varscan2
- YPEL1 | c.108C>A p.L36= | Silent (SNP) | VAF 3/42 reads (7%) | called by muse, mutect2
